Gene-level copy-number profile of tumor specimen TCGA-CV-7423-01A from TCGA case TCGA-CV-7423, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 65.9 years (24,071 days).
Specimen TCGA-CV-7423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.113eab5b-74da-4b98-bf79-405690f9d86e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7423-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-CV-7423-01A|TCGA-CV-7423-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4af9d24-e959-4697-83d7-490a49d5c527

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 135; copy number 2: 6,906; copy number 3: 8,782; copy number 4: 23,009; copy number 5: 8,876; copy number 6: 10,019; copy number 7: 372; copy number 8: 1,043; copy number 9: 353; copy number 10: 61; copy number 11: 53; copy number 12: 3; copy number 13: 8; copy number 15: 38; copy number 16: 94; copy number 21: 4; copy number 24: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7423-01A-11D-2077-01): tumor purity 0.47, ploidy 4.27, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:76,758,554–79,877,770, 48 genes (within-gene range 0–11): AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P, LINC01088, NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 623 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:75,269,068–76,802,426, 41 genes, copy number 11–12 (within-gene range 0–12): AC025244.1, AC025244.2, LINC02483, AC096759.1, AC096759.2, RCHY1, THAP6, ODAPH, CDKL2, G3BP2, Y_RNA, USO1, AC110615.1, RNU2-16P, PPEF2, NAAA, SDAD1, SDAD1-AS1, CXCL9, ART3, CXCL10, CXCL11, AC112719.1, NUP54, AC110795.1, SCARB2, FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1.
- chr5:58,198–19,234,487, 353 genes, copy number 9 (broad region; genes not listed).
- chr7:91,940,862–94,783,525, 58 genes, copy number 10–13 (within-gene range 4–13): AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2, AC002074.1, AC002074.2, COL1A2, RNU6-1328P, CASD1, SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3.
- chr11:34,335,118–36,697,867, 47 genes, copy number 15–24: MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1.
- chr11:40,083,710–47,164,385, 124 genes, copy number 10–21 (within-gene range 5–21) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 135. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
